Somatic mutation profile of tumor specimen C3N-06051-03 (aliquot CPT0439030009) from CPTAC case C3N-06051, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 77.8 years (28,424 days).
Specimen C3N-06051-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f75711ba-8e12-4843-ba48-149352776c2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06051-31 (Blood Derived Normal), aliquot CPT0444870005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22c8c446-8763-4b1b-8460-b4b2583718a5

The open-access MAF lists 252 somatic variants for this specimen: 183 protein-altering or splice-affecting, 68 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 68, Nonsense Mutation 9, Splice Region 2, Translation Start Site 1, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.2404C>T p.R802* | Nonsense Mutation (SNP) | VAF 109/430 reads (25%) | catalogued as rs201738885; called by muse, mutect2, varscan2
- ABCB1 | c.2855C>T p.S952F | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55955895; called by muse, mutect2, varscan2
- ABCB8 | c.293C>T p.P98L (on ENST00000297504 / NM_001282291.2; = p.P81L on NM_007188.5) | Missense Mutation (SNP) | VAF 126/1102 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.83); catalogued as COSV52509495; called by muse, mutect2, varscan2
- AC099489.1 | c.6238C>G p.H2080D | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs1016058906; called by muse, mutect2, varscan2
- ALPP | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 191/843 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218310613; called by muse, mutect2, varscan2
- ARHGAP31 | c.3985C>T p.P1329S | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs145865821; called by muse, mutect2, varscan2
- ATR | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.005); catalogued as COSV100638667; called by muse, mutect2, varscan2
- ATRX | c.5419C>T p.L1807F | Missense Mutation (SNP) | VAF 180/244 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64881693; called by muse, mutect2, varscan2
- BAD | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1484041309, COSV54185477; called by muse, mutect2, varscan2
- BSN | c.9083C>T p.P3028L | Missense Mutation (SNP) | VAF 129/596 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99608057; called by muse, mutect2, varscan2
- CABLES2 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 92/395 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765414889; called by muse, mutect2, varscan2
- CASR | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 85/248 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV99949242; called by muse, mutect2, varscan2
- CCDC130 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 65/511 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.063); catalogued as rs750602753; called by muse, mutect2, varscan2
- CD109 | c.3384G>T p.E1128D | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV99755087; called by muse, mutect2, varscan2
- CDH8 | c.264C>A p.D88E | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as COSV54890273; called by muse, mutect2
- CES2 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 213/433 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57697253; called by muse, mutect2, varscan2
- CFAP97 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 52/471 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs897037224, COSV71712876; called by muse, mutect2, varscan2
- CHADL | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 319/630 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1312440817; called by muse, mutect2, varscan2
- COL12A1 | c.8419C>T p.R2807C | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420946359, COSV100485791; called by muse, mutect2, varscan2
- COL16A1 | c.2512C>A p.P838T | Missense Mutation (SNP) | VAF 228/532 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as COSV54702241; called by muse, mutect2, varscan2
- COL1A2 | c.3187G>A p.G1063R | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562907861; called by muse, mutect2, varscan2
- COL3A1 | c.3592G>A p.G1198S | Missense Mutation (SNP) | VAF 160/416 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.033); catalogued as rs1254502705; called by muse, mutect2, varscan2
- CTNS | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as CM031155; called by muse, mutect2, varscan2
- DDX3X | c.1048C>T p.R350W (on ENST00000399959; = p.R351W on NM_001356.5) | Missense Mutation (SNP) | VAF 239/295 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67864267; called by muse, mutect2, varscan2
- DEGS2 | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 119/441 reads (27%) | catalogued as COSV59783358; called by muse, mutect2, varscan2
- DNAH3 | c.5866C>T p.L1956F | Missense Mutation (SNP) | VAF 48/399 reads (12%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.937); catalogued as COSV99765171; called by muse, varscan2
- DNAJB8 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 131/375 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs374250309; called by muse, mutect2, varscan2
- DNER | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs146813937; called by muse, mutect2, varscan2
- DSP | c.8492C>T p.S2831L | Missense Mutation (SNP) | VAF 58/544 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs761243454, COSV100673051; called by muse, mutect2
- EFCAB6 | c.4369G>A p.A1457T | Missense Mutation (SNP) | VAF 75/390 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.904); catalogued as rs751667777; called by muse, mutect2, varscan2
- EPHA3 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 60/500 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs773846066, COSV60708175; called by muse, mutect2, varscan2
- EPHA6 | c.2203G>A p.E735K (on ENST00000389672 / NM_001080448.3; = p.E127K on NM_173655.4) | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1454303482, COSV67567380; called by muse, mutect2, varscan2
- F2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 144/560 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV61314929, COSV61317280; called by muse, mutect2, varscan2
- FAM83B | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 282/571 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs749029751; called by muse, mutect2, varscan2
- FRMD3 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 49/363 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs753230861, COSV100171106; called by muse, mutect2, varscan2
- FST | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 264/467 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs781612641; called by muse, mutect2, varscan2
- GALNTL5 | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 45/659 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1438628622; called by muse, mutect2
- GFER | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 200/463 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as rs1472331160; called by muse, mutect2, varscan2
- GPR158 | c.2474G>C p.R825T | Missense Mutation (SNP) | VAF 90/390 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100892935; called by muse, mutect2, varscan2
- GRIN2A | c.2759G>A p.R920K | Missense Mutation (SNP) | VAF 209/408 reads (51%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.535); catalogued as COSV58023382; called by muse, mutect2, varscan2
- GTF3C1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 137/293 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1340597679, COSV62240781; called by muse, mutect2, varscan2
- HCRTR2 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 252/552 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.077); catalogued as rs1406582957, COSV63793509; called by muse, mutect2, varscan2
- HHIP | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 149/278 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.763); catalogued as COSV56842651; called by muse, mutect2, varscan2
- IVL | c.1385A>C p.N462T | Missense Mutation (SNP) | VAF 68/661 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV64216068; called by mutect2, varscan2
- KIAA1549L | c.1882+4C>T | Splice Region (SNP) | VAF 209/379 reads (55%) | catalogued as COSV99684126; called by muse, varscan2
- KIAA1958 | c.2030C>T p.S677F | Missense Mutation (SNP) | VAF 68/789 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs745588807; called by muse, mutect2
- LCN9 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs751912447; called by muse, mutect2
- LRRC55 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 174/337 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.144); catalogued as rs780168427; called by muse, mutect2, varscan2
- LRTM1 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 79/354 reads (22%) | catalogued as rs532949078, COSV55524497; called by muse, mutect2, varscan2
- MED15 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 178/434 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1199606447; called by muse, mutect2, varscan2
- MGAM | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 391/719 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV72073666; called by muse, mutect2, varscan2
- MUC16 | c.1629G>A p.M543I | Missense Mutation (SNP) | VAF 121/388 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV67488017; called by muse, mutect2, varscan2
- NEURL3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 139/297 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV60440675; called by muse, mutect2, varscan2
- NF1 | c.7489C>T p.P2497S (on ENST00000358273 / NM_001042492.3; = p.P2476S on NM_000267.3) | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.038); catalogued as rs1336098547; called by muse, mutect2, varscan2
- NFASC | c.786G>A p.M262I (on ENST00000339876 / NM_001378329.1; = p.M273I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs866745499, COSV58379670; called by muse, mutect2, varscan2
- NKX3-2 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 202/546 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as rs761027159; called by muse, mutect2, varscan2
- NRP2 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 80/392 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.328); catalogued as rs751370729; called by muse, mutect2, varscan2
- NSUN5 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs1395645249; called by muse, mutect2, varscan2
- OR13C4 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 125/544 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs995889248; called by muse, mutect2, varscan2
- OR4A47 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 167/397 reads (42%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as COSV71445173; called by muse, mutect2, varscan2
- OR4C6 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 106/548 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs778887173; called by muse, mutect2, varscan2
- PCDH17 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 96/327 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.603); catalogued as rs1254177384, COSV64978445; called by muse, mutect2, varscan2
- PCDH17 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs149002900, COSV64975035; called by muse, mutect2, varscan2
- PCNX2 | c.4769G>A p.G1590E | Missense Mutation (SNP) | VAF 94/456 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866800257; called by muse, mutect2, varscan2
- PDZD2 | c.3212G>A p.G1071E | Missense Mutation (SNP) | VAF 271/426 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV56854562, COSV99226249; called by muse, mutect2, varscan2
- PHF2 | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as rs149241220; called by muse, mutect2, varscan2
- PPARG | c.1109C>T p.S370F (on ENST00000287820 / NM_015869.5; = p.S340F on NM_005037.7) | Missense Mutation (SNP) | VAF 260/477 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs1215517121; called by muse, mutect2, varscan2
- PTPRT | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.789); catalogued as COSV100628381, COSV61977469; called by muse, mutect2, varscan2
- RGSL1 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 39/336 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1458567397, COSV54259251; called by muse, mutect2, varscan2
- SCN1B | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 101/464 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs180943300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCRG1 | c.180G>A p.W60* | Nonsense Mutation (SNP) | VAF 52/371 reads (14%) | catalogued as COSV56636244; called by muse, mutect2, varscan2
- SERPINI2 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546642713, COSV52987651; called by muse, mutect2, varscan2
- SETD1A | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 144/303 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.041); catalogued as rs747040445, COSV52686912; called by muse, mutect2, varscan2
- SLCO1B3 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750422279, COSV53940869; called by muse, mutect2, varscan2
- SMARCAD1 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.352); catalogued as rs764886010; called by muse, mutect2, varscan2
- SMU1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as COSV68139475; called by muse, mutect2, varscan2
- SPPL3 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 67/377 reads (18%) | catalogued as COSV62234432; called by muse, mutect2, varscan2
- SRGAP3 | c.2000C>A p.P667H | Missense Mutation (SNP) | VAF 121/563 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs11708178; called by muse, mutect2, varscan2
- SSH1 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 233/379 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as rs1475410779; called by muse, mutect2, varscan2
- STON2 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.481); catalogued as COSV50856441; called by muse, mutect2, varscan2
- TEK | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 128/305 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.26); catalogued as COSV66227954; called by muse, mutect2, varscan2
- TENM2 | c.2567G>A p.G856E (on ENST00000518659 / NM_001122679.2; = p.G624E on NM_001080428.3) | Missense Mutation (SNP) | VAF 159/289 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV101318495; called by muse, mutect2, varscan2
- TNFSF8 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 184/424 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs371300725; called by muse, mutect2, varscan2
- TRIOBP | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 60/424 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as rs1287373841; called by muse, mutect2, varscan2
- TTN | c.22183G>A p.G7395R (on ENST00000591111; = p.G6468R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/247 reads (18%) | PolyPhen benign (0.226); catalogued as COSV60128051; called by muse, mutect2, varscan2
- TTN | c.6949C>T p.R2317C (on ENST00000591111; = p.R2271C on NM_003319.4) | Missense Mutation (SNP) | VAF 53/342 reads (15%) | PolyPhen probably damaging (0.998); catalogued as rs750101152, COSV59975972; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBR4 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV64386751; called by muse, mutect2
- UBXN11 | c.1397C>T p.A466V (on ENST00000374221 / NM_183008.2; = p.A433V on NM_145345.2) | Missense Mutation (SNP) | VAF 74/771 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs1191665344; called by muse, mutect2
- USP35 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 43/359 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs753444653; called by muse, mutect2, varscan2
- WDR74 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs771915719, COSV53681337; called by muse, mutect2, varscan2
- WIPF2 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751625573; called by muse, mutect2, varscan2
- YRDC | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 104/571 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs1453642341; called by muse, mutect2, varscan2
- AKAP6 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 145/550 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANKRD26 | c.958G>C p.V320L | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- BICDL1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 191/311 reads (61%) | called by muse, mutect2, varscan2
- BMP2K | c.2847C>A p.S949R | Missense Mutation (SNP) | VAF 111/339 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CCDC138 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 74/295 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CFAP43 | c.1979G>A p.G660E | Missense Mutation (SNP) | VAF 146/250 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLGN | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- DSCAM | c.4897A>G p.S1633G | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- DTL | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 240/369 reads (65%) | SIFT tolerated (0.56); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DUXB | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EDN3 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 188/425 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- EPM2AIP1 | c.716A>T p.Q239L | Missense Mutation (SNP) | VAF 168/382 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ERN1 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ETV3 | c.467A>G p.D156G | Missense Mutation (SNP) | VAF 308/445 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FAM178B | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 217/435 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FBXO3 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 136/248 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- FER | c.1818A>T p.L606F | Missense Mutation (SNP) | VAF 471/584 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FGFR3 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 46/566 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.011); called by muse, mutect2
- FXR1 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- GFM2 | c.1571A>G p.D524G | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GHR | c.119A>C p.N40T | Missense Mutation (SNP) | VAF 56/574 reads (10%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.146); called by muse, mutect2
- GPR137C | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 61/365 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- GPR50 | c.65A>T p.E22V | Missense Mutation (SNP) | VAF 321/409 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GPR75 | c.758T>C p.M253T | Missense Mutation (SNP) | VAF 251/466 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HAMP | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 113/303 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HTR2C | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IDO2 | c.487A>C p.S163R (on ENST00000389060; = p.S176R on NM_194294.2) | Missense Mutation (SNP) | VAF 95/331 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IFFO1 | c.1346G>A p.G449E (on ENST00000396840 / NM_001330324.2; = p.G452E on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/322 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- IGSF9 | c.3006G>A p.W1002* (on ENST00000368094 / NM_001135050.2; = p.W986* on NM_020789.4) | Nonsense Mutation (SNP) | VAF 435/655 reads (66%) | called by muse, mutect2, varscan2
- IRF2 | c.570A>C p.Q190H | Missense Mutation (SNP) | VAF 232/409 reads (57%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRF6 | c.764A>C p.D255A | Missense Mutation (SNP) | VAF 53/392 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ITSN2 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 61/388 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- KCNQ5 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 155/554 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- KIF5C | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 72/458 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- KLF18 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 55/906 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2
- LAMC2 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 20/349 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- LEP | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LMNB1 | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 79/353 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC55 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 110/593 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); called by muse, mutect2
- LRRIQ3 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MAP2 | c.2503C>A p.P835T | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCF2L | c.1984G>C p.D662H (on ENST00000375608; = p.D630H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- MCM8 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MROH2A | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- MRTFA | c.3019A>G p.T1007A | Missense Mutation (SNP) | VAF 295/566 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MYH13 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- MYH13 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NEIL2 | c.493T>C p.L165= | Splice Region (SNP) | VAF 117/203 reads (58%) | called by muse, mutect2, varscan2
- NISCH | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 138/622 reads (22%) | called by muse, varscan2
- NOBOX | c.881A>C p.D294A | Missense Mutation (SNP) | VAF 36/704 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- NONO | c.947T>C p.L316S | Missense Mutation (SNP) | VAF 149/198 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- OR13C2 | c.817T>G p.L273V | Missense Mutation (SNP) | VAF 46/464 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2
- OR2J2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 248/825 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR7G2 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- P2RX5 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 152/305 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- P3H2 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 124/227 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- P4HA1 | c.65T>A p.F22Y | Missense Mutation (SNP) | VAF 106/196 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PCDHB11 | c.2233C>T p.L745F | Missense Mutation (SNP) | VAF 113/406 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PLXDC2 | c.113-1G>A p.X38_splice | Splice Site (SNP) | VAF 47/210 reads (22%) | called by muse, mutect2, varscan2
- RASA2 | c.-17_11del | Translation Start Site (DEL) | VAF 56/225 reads (25%) | called by mutect2, pindel, varscan2
- RFX1 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RHOJ | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN9A | c.4100G>C p.R1367P (on ENST00000303354; = p.R1356P on NM_002977.3) | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- SELPLG | c.680C>A p.T227K | Missense Mutation (SNP) | VAF 153/599 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SEMA6C | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 382/604 reads (63%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SEPTIN8 | c.721G>C p.G241R | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERGEF | c.240A>T p.Q80H | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINA10 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 262/633 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SETD1A | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 134/302 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SHANK1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 82/261 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIPA1L3 | c.3877C>T p.P1293S | Missense Mutation (SNP) | VAF 157/374 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLC14A2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 83/296 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- SRPRA | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- STK31 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 254/397 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STPG1 | c.236C>G p.P79R (on ENST00000337248 / NM_001199013.2; = p.P32R on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- STYXL2 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 281/456 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TAF1B | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TLE6 | c.362A>C p.E121A | Missense Mutation (SNP) | VAF 103/341 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- TMEM144 | c.1001T>C p.L334S | Missense Mutation (SNP) | VAF 42/344 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TRPM2 | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 97/216 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TSSK2 | c.74A>C p.K25T | Missense Mutation (SNP) | VAF 90/420 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- UNC13D | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 156/393 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- VENTX | c.195G>C p.E65D | Missense Mutation (SNP) | VAF 30/616 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.071); called by muse, mutect2
- ZFYVE9 | c.2251G>T p.V751L | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); called by muse, mutect2
- ZNF157 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 118/428 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF41 | c.2006G>A p.G669E | Missense Mutation (SNP) | VAF 55/412 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- ZNF80 | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.313); called by muse, mutect2
- ZNF845 | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- ZNF875 | c.1356G>A p.W452* | Nonsense Mutation (SNP) | VAF 179/439 reads (41%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.3335_3352del p.T1112_G1117del | In Frame Del (DEL) | VAF 44/455 reads (10%) | called by mutect2, pindel
- ZZZ3 | c.2683G>A p.D895N | Missense Mutation (SNP) | VAF 13/406 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCB8 | c.1479C>T p.F493= (on ENST00000297504 / NM_001282291.2; = p.F476= on NM_007188.5) | Silent (SNP) | VAF 694/957 reads (73%) | called by muse, mutect2, varscan2
- ALB | c.897G>A p.L299= | Silent (SNP) | VAF 51/396 reads (13%) | called by muse, mutect2, varscan2
- APLNR | c.1062C>T p.P354= | Silent (SNP) | VAF 127/536 reads (24%) | catalogued as rs376524097; called by muse, mutect2, varscan2
- APOB | c.11190C>T p.F3730= | Silent (SNP) | VAF 42/357 reads (12%) | catalogued as rs75165693, COSV51924522; called by muse, mutect2, varscan2
- ARHGAP33 | c.717C>T p.P239= | Silent (SNP) | VAF 89/343 reads (26%) | called by muse, mutect2, varscan2
- C2orf16 | c.834T>C p.D278= | Silent (SNP) | VAF 39/367 reads (11%) | called by muse, mutect2, varscan2
- C5 | c.1158C>T p.V386= | Silent (SNP) | VAF 70/230 reads (30%) | called by muse, mutect2
- C6orf47 | c.711C>T p.S237= | Silent (SNP) | VAF 41/822 reads (5%) | called by muse, mutect2
- CAPN2 | c.375C>T p.V125= | Silent (SNP) | VAF 54/401 reads (13%) | catalogued as rs781690667; called by muse, mutect2, varscan2
- CARM1 | c.369C>T p.I123= | Silent (SNP) | VAF 50/216 reads (23%) | called by muse, mutect2, varscan2
- CCR1 | c.810C>T p.T270= | Silent (SNP) | VAF 157/337 reads (47%) | catalogued as rs369715514; called by muse, mutect2, varscan2
- CCT6A | c.954G>A p.R318= | Silent (SNP) | VAF 38/410 reads (9%) | catalogued as rs1319088367; called by muse, mutect2
- CDH6 | c.1329G>A p.S443= | Silent (SNP) | VAF 200/337 reads (59%) | catalogued as rs142200699; called by muse, mutect2, varscan2
- CHD8 | c.33C>T p.D11= | Silent (SNP) | VAF 95/263 reads (36%) | called by muse, mutect2, varscan2
- CHL1 | c.1158C>T p.I386= (on ENST00000397491 / NM_001253387.1; = p.I402= on NM_006614.4) | Silent (SNP) | VAF 96/467 reads (21%) | catalogued as rs749151946; called by muse, mutect2, varscan2
- CMTM1 | c.309G>A p.K103= (on ENST00000457188 / NM_181269.3; = p.K220= on NM_052999.4) | Silent (SNP) | VAF 41/311 reads (13%) | catalogued as rs1166560704; called by muse, mutect2, varscan2
- COL6A3 | c.5176C>T p.L1726= | Silent (SNP) | VAF 116/403 reads (29%) | called by muse, mutect2, varscan2
- CPZ | c.1323G>A p.G441= (on ENST00000360986 / NM_001014447.3; = p.G430= on NM_003652.3) | Silent (SNP) | VAF 139/414 reads (34%) | called by muse, mutect2, varscan2
- CSN2 | c.366G>A p.T122= | Silent (SNP) | VAF 60/501 reads (12%) | catalogued as rs185772786, COSV61991870; called by muse, mutect2, varscan2
- DLX2 | c.621C>T p.F207= | Silent (SNP) | VAF 44/307 reads (14%) | called by muse, mutect2, varscan2
- EXO5 | c.459G>A p.L153= | Silent (SNP) | VAF 57/465 reads (12%) | called by muse, mutect2, varscan2
- FYB1 | c.1617C>T p.I539= | Silent (SNP) | VAF 222/366 reads (61%) | called by muse, mutect2, varscan2
- GCNT4 | c.1185T>G p.A395= | Silent (SNP) | VAF 87/408 reads (21%) | called by muse, mutect2, varscan2
- HYDIN | c.8274C>T p.F2758= | Silent (SNP) | VAF 23/190 reads (12%) | catalogued as rs1481797886; called by muse, mutect2, varscan2
- IDO1 | c.1063C>T p.L355= | Silent (SNP) | VAF 212/340 reads (62%) | called by muse, mutect2, varscan2
- IQGAP3 | c.3429G>A p.G1143= | Silent (SNP) | VAF 44/462 reads (10%) | called by muse, mutect2
- ITGB6 | c.1962G>A p.A654= | Silent (SNP) | VAF 149/300 reads (50%) | catalogued as rs201818641, COSV51796580; called by muse, mutect2, varscan2
- ITIH1 | c.342G>A p.K114= | Silent (SNP) | VAF 163/346 reads (47%) | catalogued as rs549599741, COSV56258701; called by muse, mutect2, varscan2
- ITPRID1 | c.504C>T p.F168= | Silent (SNP) | VAF 120/486 reads (25%) | called by muse, mutect2, varscan2
- JUND | c.348C>T p.T116= | Silent (SNP) | VAF 114/393 reads (29%) | catalogued as rs149080014; called by muse, mutect2, varscan2
- KCND3 | c.912C>T p.S304= | Silent (SNP) | VAF 206/638 reads (32%) | called by muse, mutect2, varscan2
- KLF18 | c.930C>T p.T310= | Silent (SNP) | VAF 66/1282 reads (5%) | called by muse, mutect2
- LIN9 | c.1390C>T p.L464= (on ENST00000366808 / NM_001270410.2; = p.L409= on NM_173083.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 154/325 reads (47%) | catalogued as rs773191814; called by muse, mutect2, varscan2
- LRAT | c.12C>T p.P4= | Silent (SNP) | VAF 51/266 reads (19%) | catalogued as CD127891; called by muse, mutect2, varscan2
- LTBP1 | c.1482C>T p.S494= (on ENST00000404816 / NM_206943.4; = p.S168= on NM_000627.4) | Silent (SNP) | VAF 137/271 reads (51%) | catalogued as rs760753760; called by muse, mutect2, varscan2
- MAU2 | c.1584C>T p.L528= | Silent (SNP) | VAF 84/269 reads (31%) | catalogued as rs368722872; called by muse, mutect2, varscan2
- MLLT1 | c.1173C>T p.F391= | Silent (SNP) | VAF 37/264 reads (14%) | catalogued as rs764874648; called by muse, mutect2, varscan2
- NAALAD2 | c.807C>T p.F269= | Silent (SNP) | VAF 67/180 reads (37%) | catalogued as rs1182820230; called by muse, mutect2, varscan2
- OR4Q2 | c.375T>C p.V125= | Silent (SNP) | VAF 81/405 reads (20%) | called by muse, mutect2, varscan2
- OR5R1 | c.339C>T p.F113= | Silent (SNP) | VAF 87/381 reads (23%) | catalogued as COSV56573679; called by muse, mutect2, varscan2
- PAGE2 | c.9G>A p.E3= | Silent (SNP) | VAF 35/196 reads (18%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1176C>T p.F392= | Silent (SNP) | VAF 96/1084 reads (9%) | called by muse, mutect2
- PCDHGA6 | c.1098C>T p.I366= | Silent (SNP) | VAF 106/359 reads (30%) | catalogued as rs868598149; called by muse, mutect2, varscan2
- PCOLCE | c.909G>A p.P303= | Silent (SNP) | VAF 40/325 reads (12%) | catalogued as rs765373851; called by muse, mutect2, varscan2
- PM20D1 | c.1317C>T p.F439= | Silent (SNP) | VAF 44/441 reads (10%) | called by muse, mutect2
- PPP1R13B | c.852A>G p.E284= | Silent (SNP) | VAF 42/420 reads (10%) | catalogued as rs374135998; called by muse, mutect2
- PRR23B | c.789C>T p.F263= | Silent (SNP) | VAF 42/210 reads (20%) | catalogued as COSV61494888; called by muse, mutect2, varscan2
- PTPRK | c.948G>A p.S316= | Silent (SNP) | VAF 181/335 reads (54%) | catalogued as rs996717452; called by muse, mutect2, varscan2
- RAD51AP2 | c.1680G>A p.K560= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as COSV67587666; called by muse, mutect2, varscan2
- RBPJL | c.1137G>A p.L379= | Silent (SNP) | VAF 101/527 reads (19%) | called by muse, mutect2, varscan2
- SHANK1 | c.636G>A p.S212= | Silent (SNP) | VAF 81/262 reads (31%) | catalogued as rs759830814; called by muse, mutect2, varscan2
- SLC4A5 | c.2247C>T p.I749= | Silent (SNP) | VAF 53/494 reads (11%) | catalogued as COSV61025379; called by muse, mutect2, varscan2
- SNAP91 | c.1014C>T p.V338= | Silent (SNP) | VAF 38/390 reads (10%) | catalogued as rs1244316751, COSV52128970; called by muse, mutect2
- SPTBN4 | c.5185C>T p.L1729= | Silent (SNP) | VAF 133/344 reads (39%) | catalogued as rs572199299; called by muse, mutect2, varscan2
- SSU72P8 | c.495C>T p.S165= | Silent (SNP) | VAF 73/441 reads (17%) | catalogued as rs373001008, COSV66361239; called by muse, mutect2, varscan2
- STING1 | c.894C>T p.I298= | Silent (SNP) | VAF 89/318 reads (28%) | catalogued as rs1310490983; called by muse, mutect2, varscan2
- SULF2 | c.2385G>A p.V795= | Silent (SNP) | VAF 55/268 reads (21%) | catalogued as rs1191009075, COSV63416119; called by muse, mutect2, varscan2
- TCP11X2 | c.828C>T p.S276= | Silent (SNP) | VAF 74/1252 reads (6%) | catalogued as rs1221872844; called by muse, mutect2
- TEKT4 | c.786C>T p.A262= | Silent (SNP) | VAF 235/532 reads (44%) | catalogued as rs1553395853, COSV99726702; called by muse, mutect2, varscan2
- TGIF2LX | c.378G>A p.T126= | Silent (SNP) | VAF 153/374 reads (41%) | called by muse, mutect2, varscan2
- THRB | c.570G>A p.K190= | Silent (SNP) | VAF 153/341 reads (45%) | called by muse, mutect2, varscan2
- TKFC | c.414G>A p.G138= | Silent (SNP) | VAF 138/361 reads (38%) | called by muse, mutect2, varscan2
- TMEM114 | c.345C>T p.I115= | Silent (SNP) | VAF 257/502 reads (51%) | catalogued as COSV71428765; called by muse, mutect2, varscan2
- TMEM80 | c.312C>T p.A104= (on ENST00000526170 / NM_001276274.1; = p.A166= on NM_174940.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 396/570 reads (69%) | called by muse, mutect2, varscan2
- TRPV2 | c.1581C>T p.I527= | Silent (SNP) | VAF 92/236 reads (39%) | catalogued as rs1237727649; called by muse, mutect2, varscan2
- UBE2C | c.72G>A p.G24= | Silent (SNP) | VAF 80/445 reads (18%) | called by muse, mutect2, varscan2
- XRRA1 | c.1545G>A p.P515= | Silent (SNP) | VAF 69/426 reads (16%) | catalogued as rs368615662; called by muse, mutect2, varscan2
- ZNF845 | c.2646T>G p.T882= | Silent (SNP) | VAF 137/341 reads (40%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.857C>T | RNA (SNP) | VAF 104/287 reads (36%) | catalogued as rs767551988, COSV55602116; called by muse, mutect2, varscan2
